Somatic mutation profile of tumor specimen TCGA-HT-A5R7-01A (aliquot TCGA-HT-A5R7-01A-11D-A289-08) from TCGA case TCGA-HT-A5R7, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.1 years (12,092 days).
Specimen TCGA-HT-A5R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42e2a921-f7d1-4cfb-91e6-5e708d004929.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A5R7-10A (Blood Derived Normal), aliquot TCGA-HT-A5R7-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/870311e5-2a04-4f2b-b525-4621b2273abc

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 16, Silent 9, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AOC1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs577618065, COSV62869491; called by muse, mutect2, varscan2
- ATRX | c.3897dup p.K1300Efs*9 | Frame Shift Ins (INS) | VAF 28/107 reads (26%) | catalogued as COSV64871730; called by mutect2, pindel, varscan2
- DEDD2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 2/21 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56630290; called by muse, mutect2
- FAM47B | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV61454821; called by muse, mutect2
- FLT4 | c.670A>T p.I224F | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV99986327; called by muse, mutect2
- FOXN1 | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs761946932, COSV56882576; called by muse, mutect2, varscan2
- MUC17 | c.10060A>T p.S3354C | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60293277; called by muse, mutect2
- MYEOV | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs752728278, COSV58294676; called by muse, mutect2, varscan2
- NOL3 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.071); catalogued as COSV50457952; called by muse, mutect2, varscan2
- NUP210 | c.4993C>G p.L1665V | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV54408515; called by muse, mutect2, varscan2
- SIGLEC9 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.142); catalogued as rs151265101; called by muse, mutect2, varscan2
- SLC5A8 | c.976T>A p.L326M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV101610520; called by muse, mutect2
- TOMM70 | c.1031A>G p.N344S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.026); catalogued as rs748687788, COSV52523936; called by muse, mutect2, varscan2
- UNC79 | c.3674G>A p.R1225H (on ENST00000393151 / NM_001346218.2; = p.R1048H on NM_020818.5) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1179332328, COSV56406284; called by muse, mutect2
- VIL1 | c.1510T>C p.S504P | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV50290430; called by muse, mutect2, varscan2
- XG | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV66985811; called by muse, mutect2, varscan2
- GKAP1 | c.650_666del p.V217Efs*12 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- ACKR2 | c.987C>T p.A329= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs1177934010, COSV56178511; called by muse, mutect2
- FBLN2 | c.1590C>T p.A530= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs368630493, COSV55486678; called by muse, mutect2, varscan2
- GRHL2 | c.705T>G p.A235= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV99306374; called by muse, mutect2
- GRIN2A | c.198C>T p.D66= | Silent (SNP) | VAF 14/187 reads (7%) | catalogued as COSV58041237; called by muse, mutect2
- MED23 | c.3417A>G p.R1139= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV63433717; called by muse, mutect2, varscan2
- NUTM1 | c.1242C>A p.I414= | Silent (SNP) | VAF 13/196 reads (7%) | catalogued as COSV59217525; called by muse, mutect2
- PPM1J | c.240G>A p.L80= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV58552260; called by muse, mutect2
- RASGRP3 | c.258T>G p.P86= | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as COSV101274713, COSV67821998; called by muse, mutect2
- SEC31A | c.3472A>C p.R1158= (on ENST00000355196 / NM_001318120.1; = p.R1119= on NM_016211.4) | Silent (SNP) | VAF 51/171 reads (30%) | catalogued as COSV52347347; called by muse, mutect2, varscan2
